Somatic mutation profile of tumor specimen 0DJR1F from CCDI case PBBXJG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.4 years (3,439 days).
Specimen 0DJR1F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8938515-4e91-4072-a7ad-e4498275a58d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJQZF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c02d494f-9a4e-45e6-8505-3883ae72b1f5

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 116/500 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CSNK2A2 | c.195_196del p.R65Sfs*19 | Frame Shift Del (DEL) | VAF 66/360 reads (18%) | called by pindel, varscan2
- MTHFD1 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPAS1 | c.1006C>A p.R336S | Missense Mutation (SNP) | VAF 115/463 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SEMA6B | c.2558A>G p.E853G | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMG1 | c.684C>T p.I228= | Silent (SNP) | VAF 170/971 reads (18%) | called by muse, mutect2, varscan2
- SZT2 | c.498+13C>A | Intron (SNP) | VAF 63/380 reads (17%) | called by muse, mutect2, varscan2
